FM case AD5864 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Squamous Cell Neoplasms; Primary site: Skin.
https://portal.gdc.cancer.gov/cases/108dc494-96fa-4339-8347-a168eede8cc1

Male, 51.6 years: Squamous cell carcinoma, NOS (ICD-O-3 8070/3) of the skin; metastasis biopsied or resected from the connective, subcutaneous and other soft tissues. Tumor nuclei on the sequenced sample's slide: 60% (pathologist estimate recorded by GDC). Sample type: Metastatic.
